Surgical pathology report (de-identified scan), TCGA case TCGA-CN-A6UY, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-A6UY-01A (Primary Tumor).

[page 1 of 6]
Pathology Report

CORRECTED

Report Type Pathology Report
Date of Event
Sex
Authored by
Hosp/Group
Record Status CORRECTED

ICD-0-3
Carcinoma, squamous
cell non-keratinizing NOS
8072/3
Site Base of tongue
C01.9
JW 8/2/13

COMPREHENSIVE THERANOSTIC SUMMARY

IMMUNOHISTOCHEMISTRY:
p16:

RESULTS
POSITIVE

IN SITU HYBRIDIZATION / FISH:
HPV:
subtypes Pan
DNA probe

RESULTS
POSITIVE;

Punctate

Pattern:

**See Special Procedure reports below for additional details and background on

In situ/FISH and/or Molecular Anatomic Pathology testing as pertinent**

Pathologist:

** Report Electronically Signed Out **

By Pathologist:

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT NECK LEVEL 3, SELECTIVE DISSECTION
SEVEN LYMPH NODES, NO TUMOR PRESENT (0/7).
PART 2: LYMPH NODES, RIGHT NECK LEVEL 4, SELECTIVE DISSECTION
TWELVE LYMPH NODES, NO TUMOR PRESENT (0/12).
PART 3: LYMPH NODES, RIGHT NECK LEVEL 2, SELECTIVE DISSECTION
A. METASTATIC SQUAMOUS CELL CARCINOMA (0.5 CM AND 0.3 CM) IN
TWO OUT
OF TWENTY-FOUR LYMPH NODES (2/24).
B. NO EXTRANODAL EXTENSION PRESENT.
PART 4: BASE OF TONGUE, LEFT MARGIN, SHAVE BIOPSY
NO TUMOR PRESENT.
PART 5: TONGUE, ANTERIOR MARGIN, SHAVE BIOPSY
NO TUMOR PRESENT.
PART 6: PHARYNGEAL WALL, RIGHT MARGIN, BIOPSY

[page 2 of 6]
NO TUMOR PRESENT.
PART 7: BASE OF TONGUE, DEEP MARGIN, SHAVE BIOPSY
NO TUMOR PRESENT.
PART 8: BASE OF TONGUE, ADDITIONAL DEEP MARGIN, SHAVE BIOPSY
NO TUMOR PRESENT.
PART 9: BASE OF TONGUE, RIGHT, HEMIGLOSSECTOMY
A. INVASIVE SQUAMOUS CELL CARCINOMA (4.4 CM), PREDOMINANTLY
NON-KERATINIZING.
B. NO PERINEURAL INVASION PRESENT.
C. ALL FINAL MARGINS ARE FREE OF CARCINOMA (SEE OTHER PARTS).
D. PATHOLOGIC STAGE: pT3, N2b.

COMMENT:

A p16 immunostain and in-situ hybridization for human papilloma virus (HPV)

DNA will be performed and reported in an addendum.

Pathologist:

** Report Electronically Signed Out **

By Pathologist:

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

Part 1 is received fresh labeled with the patient's name, initials XXX, medical record number, and "right neck dissection level 3". It consists of a

4.5 x 2.5 x 1.0 cm portion of pale yellow adipose tissue and gray-white fibrous tissue. Multiple firm, tan nodules resembling lymph nodes are identified ranging from 0.3 to 1.6 cm in greatest dimension. All possible lymph nodes are submitted.

Section Code:

1A - one bisected lymph node

1B - 1C - remaining whole lymph nodes

Formalin Exposure Time: 72 Hours

Part 2 is received fresh labeled with the patient's name, initials XXX, medical record number, and "right neck dissection level 4". It consists of a

6.0 x 3.5 x 0.8 cm portion of pale yellow adipose tissue and gray-white fibrous tissue. Multiple firm, tan nodules resembling lymph nodes are identified ranging from 0.4 to 1.0 cm in greatest dimension. All possible lymph nodes are submitted.

Section Code:

2A - one bisected lymph node

2B - 2D - remaining whole lymph nodes

Formalin Exposure Time: 72 Hours

Part 3 is received fresh labeled with the patient's name, initials XXX, medical record number, and "right neck dissection level 2". It consists of a

6.5 x 4.0 x 1.0 cm portion of pale yellow adipose tissue and gray-white fibrous tissue. Multiple firm, tan nodules resembling lymph nodes are identified ranging from 0.2 to 2.7 cm in greatest dimension. All possible

[page 3 of 6]
lymph nodes are submitted.

Section Code:

3A - one bisected lymph node

3B - 3F - remaining whole lymph nodes

Formalin Exposure Time: 72 Hours

Part 4 is received fresh for intraoperative consultation labeled with the

patient's name, initials XXX, medical record number, and "left base of tongue

margin". It consists of a 1.7 x 1.2 x 0.3 cm un-oriented, tan-gray portion of

soft tissue. The specimen is entirely evaluated using frozen section. The

frozen section remnant is submitted in cassette 4AFS.

Formalin Exposure Time: 71 Hours

Part 5 is received fresh for intraoperative consultation labeled with the

patient's name, initials XXX, medical record number, and "anterior margin".

It consists of a 1.5 x 1.0 x 0.4 cm un-oriented, tan-gray portion of soft

tissue. The specimen is entirely evaluated using frozen section. The frozen

section remnant is submitted in cassette 5AFS.

Formalin Exposure Time: 71 Hours

Part 6 is received fresh for intraoperative consultation labeled with the

patient's name, initials XXX, medical record number, and "right pharyngeal

wall". It consists of a 2.5 x 0.5 x 0.3 cm un-oriented segment of tan-white

soft tissue. The specimen is entirely evaluated using frozen section. The

frozen section remnant is submitted in cassette 6AFS.

Formalin Exposure Time: 71 Hours

Part 7 is received fresh for intraoperative consultation labeled with the

patient's name, initials XXX, medical record number, and "deep base of tongue

margin". It consists of a 1.5 x 1.0 x 0.5 cm un-oriented, tan-gray portion of

soft tissue. The specimen is entirely evaluated using frozen section. The

frozen section remnant is submitted in cassette 7AFS.

Formalin Exposure Time: 71 Hours

Part 8 is received fresh labeled with the patient's name, initials XXX, medical record number, and "additional left base of tongue". It consists of a

1.9 x 0.7 x 0.4 cm un-oriented, tan-gray portion of soft tissue and a 0.5 x

0.5 x 0.2 cm aggregate of tan-gray tissue fragments. All tissue is submitted

in cassette 8A.

Formalin Exposure Time: 72 Hours

Part 9 is received fresh labeled with the patient's name, initials XXX, medical record number, and "right base of tongue, short stitch

pharyngeal,

[page 4 of 6]
long stitch anterior". It consists of a 6.4 x 3.5 x 1.7 cm oriented right base of tongue excision with a long stitch designating anterior and a short stitch designating the pharyngeal wall. There is a 4.4 x 3.3 x 1.6 cm gray-white lesion on the floor of mouth surface partially surrounded by gray mucosa at the lateral aspect. The exposed surface of the lesion is slightly friable and the cut surface is dense and smooth with infiltrative borders. The lesion abuts the anterior and deep edges and is 2.0 cm from the lateral wall. The remainder of the uninvolved specimen is composed of a brown muscular tissue surfaced by filiform gray mucosa. Digital images are taken and tissue from the lesion is banked. Representative sections from medial to lateral are submitted in cassettes 9A - 9D.

Ink Code:

Black - deep edge (not true margin)

Yellow - anterior edge (not true margin)

Red - tissue banked

Formalin Exposure Time: 72 Hours

Grossed By:

INTRAOPERATIVE CONSULTATION:

4AFS: SOFT TISSUE, LEFT BASE OF TONGUE, MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. FIBROMUSCULAR TISSUE AND SALIVARY GLAND

5AFS: SOFT TISSUE, ANTERIOR MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. MUSCULAR TISSUE

6AFS: SOFT TISSUE PHARYNX, RIGHT WALL, MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. SQUAMOUS LINED CONNECTIVE TISSUE

7AFS: SOFT TISSUE, DEEP BASE OF TONGUE, MARGIN (frozen section)

A. SUFFICIENT FOR ANCILLARY STUDIES

B. BENIGN

C. MUSCULAR TISSUE

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by

the

the CLIA

as required by

[page 5 of 6]
'88 regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical

testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory

have been established and verified for accuracy and precision.

Additional

information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND

TUMORS

SPECIMEN TYPE: Resection: Robotic right hemiglossectomy and right limited pharyngectomy.

TUMOR SITE: Pharynx, oropharynx

TUMOR SIZE: Greatest dimension: 4.4 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT3

REGIONAL LYMPH NODES (pN): pN2b

Number of regional lymph nodes examined: 43

Number of regional lymph nodes involved: 2

Extra-capsular extension of nodal tumor: Absent

DISTANT METASTASIS (pM): pMX

MARGINS: Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L): Present

PERINEURAL INVASION: Absent

ADDITIONAL PATHOLOGIC FINDINGS: None identified

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Tongue cancer.

PROCEDURE: Right neck dissection (left possible)/robotic resection tongue.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Right Neck Dissection Level 3

Taken: Received:

Stain, Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

Part 2: Right Neck Dissection Level 4

Taken: Received:

[page 6 of 6]
Stain/ Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
Part 3: Right Neck Dissection Level 2
Taken: Received:
Stain/ Block
H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
Part 4: left Base of Tongue Margin
Taken: Received:
Stain, Block
H&E x 1 AFS
Part 5: Anterior Margin
Taken: Received:
Stain, Block
H&E x 1 AFS
Part 6: Right Pharyngeal Wall Margin
Taken: Received:
Stain, Block
H&E x 1 AFS
Part 7: Deep Base of Tongue Margin
Taken: Received:
Stain/ Block
H&E x 1 AFS
Part 8: Additional Base of Tongue
Taken: Received:
Stain, Block
H&E x 1 A
Part 9: Right Base of Tongue
Taken: Received:
Stain, Block
H&E x 1 A
ANEG Mouse x 1 B
HCOM x 1 B
ISHBNK x 1 B
ISHBNK x 1 B
H&E x 1 B
HPV x 1 B
IISH x 1 B
P16 x 1 B
H&E x 1 C
H&E x 1 D
PHSU x 2 (none)
TC1

H&PAA Discrepancy		/

Source: NCI Genomic Data Commons file 50c87f67-b49b-478f-b1f9-ba99a6301d73 (TCGA-CN-A6UY.2748944D-572E-405B-9CDD-5B9D2F40C9C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).